Surgical pathology report (de-identified scan), TCGA case TCGA-HV-AA8V, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-AA8V-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: R/O Pancreatic head cancer

Specimen : CBD, Pancreatic head,

GROSS:

Specimen status: Fresh

Operation: Pylorus preserving pancreaticoduodenectomy and cholecystectomy

Organs:

Small intestine (21.0 cm in length and 5.3 cm in greatest circumference)

Pancreas, partial (6.5 x 5.5 x 3.8 cm)

Common bile duct (2.8 cm in length and 1.4 cm in diameter)

Gallbladder (13.0 cm in length and 3.7 cm in diameter)

Lesions:

An ill-defined pale tan solid and firm mass (3.5 x 3.0 x 2.8 cm) in pancreatic head

Cut surface: Yellowish tan, firm and granular

Extent: Extension to peripancreatic soft tissue and duodenal wall

Resection margin: Involved grossly

MICROSCOPIC:

Tumor type: Ductal adenocarcinoma

Tumor location: Pancreatic head

Histologic grade: Poorly differentiated

Tumor size: 3.5 x 3.0 x 2.8 cm

Extent: Peripancreatic soft tissue and duodenal wall (submucosa)

Lymphovascular invasion: Present

Perineural invasion: Present

Surgical margins: All surgical margins are free from tumor

Lymph nodes:

Lymph node, 12: No tumor present (0/2)

Lymph node, 13: Metastatic adenocarcinoma, primary in pancreas (1/1)

Lymph node, peripancreatic: Metastatic carcinoma, primary in pancreas (2/19)

DIAGNOSIS:

Pancreas, head, pylorus preserving pancreaticoduodenectomy:

Ductal adenocarcinoma, poorly differentiated, infiltrating

Small intestine, duodenum, pylorus preserving pancreaticoduodenectomy:

ICD O.3
Adenocarcinoma, duct NOS 8500/3
Site Pancreas head C25.0
JW 4/2/14

[page 2 of 2]
Direct tumor extension of pancreatic ductal adenocarcinoma

Common bile duct, pylorus preserving pancreaticoduodenectomy:

Chronic inflammation

Gallbladder, pylorus preserving pancreaticoduodenectomy:

Chronic cholecystitis

Cholesterolosis

Lymph node, pylorus preserving pancreaticoduodenectomy:

Lymph node, 12: No tumor present (0/2)

Lymph node, 13: Metastatic adenocarcinoma, primary in pancreas (1/1)

Lymph node, peripancreatic: Metastatic carcinoma, primary in pancreas (2/19)

Source: NCI Genomic Data Commons file e1094cc7-ee60-4224-a8fb-a4c61e9488d7 (TCGA-HV-AA8V.B2F0252D-63F9-4D78-BAA3-DE40F64A61D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).